Somatic mutation profile of tumor specimen 0DLHOP from CCDI case PBBRCW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Aggressive fibromatosis; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 17.1 years (6,257 days).
Specimen 0DLHOP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ee8b42c-bc69-461d-8b16-d2c28ffe5861.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLHOE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd62b32e-c41c-4851-9730-cafaccb0a2b8

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 2, Silent 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 488/1110 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CSMD1 | c.6154G>A p.A2052T (on ENST00000520002; = p.A2051T on NM_033225.6) | Missense Mutation (SNP) | VAF 216/1128 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs373726648; called by muse, mutect2, varscan2
- ZNF587B | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 159/683 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as rs777433947; called by muse, mutect2, varscan2
- ELAVL1 | c.430+2T>G p.X144_splice | Splice Site (SNP) | VAF 88/239 reads (37%) | called by muse, mutect2, varscan2
- SMTN | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 200/503 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- WDCP | c.314_321del p.T105Nfs*2 | Frame Shift Del (DEL) | VAF 148/382 reads (39%) | called by mutect2, varscan2
- DDHD1 | c.39C>T p.H13= (on ENST00000323669; = p.H244= on NM_030637.3) | Silent (SNP) | VAF 218/532 reads (41%) | catalogued as rs1228494570; called by muse, mutect2, varscan2
- HDAC5 | c.2271C>T p.L757= | Silent (SNP) | VAF 366/928 reads (39%) | catalogued as COSV56820023; called by muse, mutect2, varscan2
- ANKRD31 | c.-74C>T | 5'UTR (SNP) | VAF 74/215 reads (34%) | called by muse, mutect2, varscan2
- ZNF503 | c.-19C>T | 5'UTR (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
